Gene-level copy-number profile of tumor specimen TCGA-GS-A9TX-01A from TCGA case TCGA-GS-A9TX, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of inguinal region or leg; Age at diagnosis: 37.5 years (13,708 days).
Specimen TCGA-GS-A9TX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.cb476803-1b00-4fa5-a1ca-c70be2f1db32.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GS-A9TX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d2240d40-b66d-437b-bd83-2c855379d3b8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 21,298; copy number 2: 33,522; copy number 3: 4,927.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GS-A9TX-01A-11D-A381-01): tumor purity 0.31, ploidy 2.31, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 60 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,528,745–5,090,899, 60 genes: HES5, AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2, AL139246.3, PRXL2B, MMEL1, MMEL1-AS1, TTC34, AC242022.2, AC242022.1, AL592464.2, AL592464.3, AL592464.1, AL589702.1, ACTRT2, PRDM16-DT, PRDM16, MIR4251, AL008733.1, AL512383.1, AL590438.1, AL354743.2, AL354743.1, ARHGEF16, AL512413.1, MEGF6, MIR551A, AL513320.1, TPRG1L, WRAP73, TP73, TP73-AS3, TP73-AS2, TP73-AS1, AL136528.1, CCDC27, SMIM1, LRRC47, RN7SL574P, AL365330.1, CEP104, DFFB, C1orf174, LINC01134, LINC01346, LINC01345, LINC02780, AL805961.1, EEF1DP6, LINC01777, AL355602.1, Z98747.1, LINC01646, AJAP1, Z98886.1, BX005132.1, LINC02781, LINC02782.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 18,918. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
